Somatic mutation profile of tumor specimen TCGA-55-6975-01A (aliquot TCGA-55-6975-01A-11D-1945-08) from TCGA case TCGA-55-6975, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-55-6975-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5f0de46-8e12-4e9d-a9d4-509db39369da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6975-11A (Solid Tissue Normal), aliquot TCGA-55-6975-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/358c3717-fbaf-4d29-abe1-3a64e3f95880

The open-access MAF lists 76 somatic variants for this specimen: 61 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 14, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 22/85 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- AASS | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62788810; called by muse, mutect2, varscan2
- ADGRG3 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV59650113; called by muse, mutect2, varscan2
- ANK3 | c.207T>G p.I69M | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55043725; called by muse, mutect2, varscan2
- ARHGEF6 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as COSV51687500; called by muse, mutect2, varscan2
- BAHCC1 | c.1492A>G p.T498A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57022723; called by muse, mutect2, varscan2
- BCAS3 | c.2366G>A p.S789N (on ENST00000390652 / NM_001353144.2; = p.S774N on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.24); catalogued as COSV66769955; called by muse, mutect2, varscan2
- BRINP3 | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.594); catalogued as COSV100819101, COSV66523946; called by muse, mutect2, varscan2
- BRWD3 | c.4309G>C p.A1437P | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV64743843; called by muse, mutect2, varscan2
- CD177 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV65120756; called by muse, mutect2, varscan2
- CFAP65 | c.2026C>A p.L676M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100445458; called by muse, mutect2, varscan2
- CFAP65 | c.2025C>A p.C675* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100445462; called by muse, mutect2, varscan2
- CLEC12B | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.093); catalogued as COSV58862424; called by muse, mutect2, varscan2
- CPED1 | c.2244G>T p.Q748H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV59996976; called by muse, mutect2, varscan2
- E2F4 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1351677747, COSV58873137; called by muse, mutect2, varscan2
- ENPP5 | c.1043T>A p.M348K | Missense Mutation (SNP) | VAF 72/357 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57908016; called by muse, mutect2, varscan2
- ERC1 | c.2487G>A p.Q829= (on ENST00000360905 / NM_178040.4; = p.Q801= on NM_178039.4) | Splice Region (SNP) | VAF 6/35 reads (17%) | catalogued as COSV61691341; called by muse, mutect2, varscan2
- ERCC3 | c.1821A>G p.I607M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV53425477, COSV53429832; called by muse, mutect2, varscan2
- ERCC6L | c.3295del p.I1100Lfs*5 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | catalogued as rs769073969; called by mutect2, pindel, varscan2
- FAM71A | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs865812216, COSV54234581; called by muse, mutect2, varscan2
- FAT4 | c.7139G>A p.G2380E | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58671293; called by muse, mutect2
- GMCL1 | c.1453-2A>G p.X485_splice | Splice Site (SNP) | VAF 32/140 reads (23%) | catalogued as COSV57000429; called by muse, mutect2, varscan2
- GSDMC | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52693098, COSV52693954; called by muse, mutect2, varscan2
- INTS8 | c.242T>G p.L81* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV58248504; called by muse, mutect2, varscan2
- JARID2 | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1319707452, COSV59185090, COSV59192483; called by muse, mutect2
- KLHL24 | c.669T>G p.I223M | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV54424553; called by muse, mutect2
- LTB | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as rs768498333, COSV101068564, COSV65815042; called by muse, mutect2, varscan2
- MIDN | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56293998; called by muse, mutect2, varscan2
- MYH7 | c.5612T>C p.L1871P | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62516215; called by muse, mutect2, varscan2
- MYPN | c.2221A>T p.S741C | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV62731502; called by muse, mutect2, varscan2
- OR2T11 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); catalogued as rs369085517, COSV58184748; called by muse, mutect2, varscan2
- OR4C13 | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); catalogued as COSV73648616; called by muse, mutect2, varscan2
- PAPPA2 | c.2750C>A p.P917H | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.677); catalogued as COSV100868793, COSV62790466; called by muse, mutect2, varscan2
- PCDHA11 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs990827650, COSV56477132; called by muse, mutect2
- PKHD1L1 | c.5449G>C p.G1817R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV65736904; called by muse, mutect2, varscan2
- PKHD1L1 | c.7700C>A p.P2567Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104428535, COSV65736909; called by muse, mutect2, varscan2
- PLD1 | c.1197dup p.R400Efs*7 | Frame Shift Ins (INS) | VAF 85/336 reads (25%) | catalogued as rs748054270; called by mutect2, pindel, varscan2
- PREX1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs943188055, COSV64247751; called by muse, varscan2
- PTH1R | c.1706C>G p.S569* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | catalogued as COSV57314494; called by muse, mutect2, varscan2
- PTPRD | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61927103; called by mutect2, varscan2
- RAP2A | c.490A>T p.M164L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV55354329; called by muse, mutect2, varscan2
- RYR2 | c.5499C>G p.I1833M | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV63660786; called by muse, mutect2, varscan2
- SGO2 | c.673A>T p.I225F | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV63413832; called by muse, mutect2, varscan2
- SMARCA4 | c.3523G>A p.D1175N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298515852, COSV60786299; called by muse, mutect2, varscan2
- ST7 | c.395-2A>T p.X132_splice | Splice Site (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99622361; called by muse, varscan2
- SUN2 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV53301785; called by muse, mutect2, varscan2
- SYNGAP1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV99538670; called by muse, mutect2
- TRPC4 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58990170; called by muse, mutect2, varscan2
- TTC29 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as rs374599032, COSV100283525; called by mutect2, varscan2
- UBQLN1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV57406719; called by muse, mutect2, varscan2
- UGT1A10 | c.662A>T p.Q221L | Missense Mutation (SNP) | VAF 104/381 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60831078; called by muse, mutect2, varscan2
- USH2A | c.12802C>G p.P4268A | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.318); catalogued as COSV56326562, COSV56369025; called by muse, mutect2
- USH2A | c.4490C>A p.S1497Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.325); catalogued as rs755482100, COSV56326577; called by muse, mutect2, varscan2
- VCAN | c.10181C>T p.S3394L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs532877615, COSV54096524; called by muse, mutect2, varscan2
- ZNF521 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV64122089, COSV64129818; called by muse, mutect2, varscan2
- ERMARD | c.1137dup p.H380Tfs*2 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- TADA2A | c.1207A>G p.N403D | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TP53 | c.913_916del p.K305Efs*39 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- ZNF800 | c.185del p.L62* | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- CARD16 | c.565T>C p.L189= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1185296838, COSV65212691; called by muse, mutect2, varscan2
- CWC22 | c.1683A>G p.P561= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV55426465, COSV55431668; called by muse, mutect2, varscan2
- DSE | c.33G>T p.V11= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV59061774; called by muse, mutect2, varscan2
- FCAR | c.6C>T p.D2= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs569661269, COSV62028272; called by muse, mutect2, varscan2
- FGFBP1 | c.459C>G p.S153= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV52586074; called by muse, mutect2, varscan2
- GPCPD1 | c.1374A>T p.I458= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV66830120; called by muse, mutect2, varscan2
- HAPLN3 | c.801G>A p.R267= | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as COSV61355632; called by muse, mutect2
- KIAA1522 | c.1929C>G p.A643= (on ENST00000373480 / NM_001198972.2; = p.A702= on NM_020888.3) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs771851259, COSV53862307; called by muse, mutect2, varscan2
- LRRTM3 | c.687C>G p.V229= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV63661265; called by muse, mutect2, varscan2
- MEGF10 | c.1470A>G p.T490= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV57244852; called by muse, mutect2, varscan2
- NBEA | c.1983C>T p.G661= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV59759600; called by muse, mutect2, varscan2
- NFASC | c.1207A>C p.R403= (on ENST00000339876 / NM_001378329.1; = p.R414= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV58358464; called by muse, mutect2, varscan2
- PPARGC1A | c.1731G>A p.S577= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs146697747; called by muse, mutect2, varscan2
- TBC1D10A | c.561G>A p.T187= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs200764300, COSV53162810; called by mutect2, varscan2
- COP1 | c.2133+18431G>T | Intron (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100443580; called by muse, mutect2, varscan2
